Somatic mutation profile of tumor specimen TCGA-VS-A9UZ-01A (aliquot TCGA-VS-A9UZ-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-VS-A9UZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5e93af6-88fc-4c99-8154-521a3dd86d99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UZ-10A (Blood Derived Normal), aliquot TCGA-VS-A9UZ-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3feca4d2-01d3-449e-8610-ef1861d94a57

The open-access MAF lists 200 somatic variants for this specimen: 142 protein-altering or splice-affecting, 51 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 51, Nonsense Mutation 15, Intron 5, Frame Shift Del 2, In Frame Del 2, RNA 1, Splice Site 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV62572120, COSV62572141; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 37/76 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 87/173 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASDHPPT | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV53789192; called by muse, mutect2, varscan2
- ABHD1 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV99574566; called by muse, mutect2, varscan2
- ACTN3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as rs368474114, COSV101557849; called by muse, mutect2, varscan2
- ADAD1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56641528; called by muse, mutect2, varscan2
- ADAMTS15 | c.1765G>A p.G589S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs758826755, COSV54508023; called by muse, mutect2, varscan2
- ADGRG1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV101113444, COSV65636549; called by muse, mutect2, varscan2
- ADGRL3 | c.2379C>G p.I793M (on ENST00000506720 / NM_001322402.2; = p.I725M on NM_015236.6) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101547219; called by muse, mutect2, varscan2
- ALX4 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1014714152, COSV100241121; called by mutect2, varscan2
- ANO6 | c.48G>C p.E16D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs140379296; called by muse, varscan2
- ARHGEF9 | c.1341G>A p.M447I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99491928; called by muse, mutect2, varscan2
- ARID1A | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV61376109; called by muse, mutect2, varscan2
- ARMCX3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV100362288; called by muse, mutect2, varscan2
- ATP2C1 | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs749921964, COSV100146491, COSV100146781; called by muse, varscan2
- B2M | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV62562840, COSV62562870, COSV62563658; called by muse, mutect2, varscan2
- BIRC2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as COSV99926737; called by muse, mutect2, varscan2
- BRINP3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.026); catalogued as COSV100818610; called by muse, mutect2, varscan2
- C14orf180 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs538979526, COSV100118768; called by muse, mutect2, varscan2
- CASC3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.269); catalogued as rs892911228, COSV99229793; called by muse, mutect2, varscan2
- CCDC14 | c.1172G>A p.R391K (on ENST00000488653; = p.R343K on NM_022757.5) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.073); catalogued as COSV100113264, COSV59948136; called by muse, mutect2, varscan2
- CDC27 | c.2254C>G p.Q752E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV99295069; called by muse, mutect2, varscan2
- CENPB | c.1306G>C p.G436R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.121); catalogued as rs780602403, COSV100713480, COSV60144384; called by muse, varscan2
- CHD7 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs778361949, COSV101418284, COSV71106936; ClinVar: uncertain significance; called by muse, mutect2
- CIT | c.5852G>A p.R1951Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.805); catalogued as rs371376893; called by muse, mutect2, varscan2
- CLIC3 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100860421; called by muse, mutect2, varscan2
- CLSTN3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs149690531; called by muse, mutect2, varscan2
- CNGB1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99202862; called by muse, mutect2, varscan2
- CNOT1 | c.3506C>T p.T1169I | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99800453; called by muse, mutect2, varscan2
- COL11A1 | c.3040C>T p.Q1014* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100617015; called by muse, mutect2, varscan2
- CPXM1 | c.1360C>A p.P454T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV66045347; called by muse, mutect2
- CPZ | c.442C>T p.R148C (on ENST00000360986 / NM_001014447.3; = p.R137C on NM_003652.3) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs377251041; called by muse, mutect2, varscan2
- CYP2B6 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100137593; called by muse, mutect2, varscan2
- DHX34 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as rs146308675; called by mutect2, varscan2
- DHX8 | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV99292332; called by muse, mutect2, varscan2
- DLEU7 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.263); catalogued as rs1444238537, COSV101246840; called by muse, mutect2
- DLGAP5 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99903944; called by muse, mutect2
- DMD | c.7892G>A p.R2631H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs748007790, COSV100627737; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH9 | c.5827C>T p.Q1943* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV52344070; called by muse, mutect2
- DOCK4 | c.5160G>C p.E1720D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as rs370179180; called by muse, mutect2, varscan2
- DST | c.6919C>G p.Q2307E | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as COSV55033093, COSV99757322; called by muse, mutect2, varscan2
- ERBIN | c.2566C>G p.L856V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs761751803, COSV99397068; called by muse, mutect2, varscan2
- ERBIN | c.2801C>T p.S934F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99397070; called by muse, mutect2, varscan2
- ERBIN | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV52326534, COSV99397893; called by muse, mutect2, varscan2
- ERP29 | c.566C>G p.S189* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99923616; called by muse, mutect2, varscan2
- ETV1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV99623739; called by muse, mutect2, varscan2
- FAM133A | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100220442; called by muse, mutect2, varscan2
- FAM47B | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as rs1188128691, COSV100264134; called by muse, mutect2
- FLNA | c.5643C>G p.N1881K (on ENST00000369850 / NM_001110556.2; = p.N1873K on NM_001456.3) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100774820; called by muse, mutect2, varscan2
- GALNT13 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101223257, COSV101224409; called by muse, mutect2, varscan2
- GATD1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758640162, COSV100168695; called by muse, mutect2
- GBA | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs759983265, COSV100516368, COSV59169753; called by muse, mutect2, varscan2
- GIMAP6 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs200301890, COSV61035384; called by muse, mutect2, varscan2
- GNAS | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100006781; called by muse, mutect2, varscan2
- H4C12 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100694797; called by muse, mutect2, varscan2
- HAPLN1 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99165003; called by muse, mutect2
- HLTF | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59498536; called by muse, mutect2, varscan2
- IGF2R | c.7330C>T p.Q2444* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV63631176; called by muse, mutect2
- IGHD | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as COSV101162910; called by muse, mutect2
- KCNA1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV101230287; called by muse, mutect2
- KDM1B | c.443G>C p.R148T | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99924341; called by muse, mutect2
- KIAA1549L | c.937C>T p.P313S (on ENST00000321505; = p.P610S on NM_012194.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); catalogued as COSV99683709; called by muse, mutect2, varscan2
- KIAA1958 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100516168; called by muse, mutect2, varscan2
- KIAA2026 | c.5882G>C p.R1961T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV101199087; called by muse, mutect2
- KLHDC10 | c.279T>G p.S93R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100110947; called by muse, mutect2, varscan2
- KRT1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554536645, COSV52866582; called by muse, mutect2, varscan2
- MAP3K15 | c.2370C>G p.I790M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100134930; called by muse, mutect2, varscan2
- MED13L | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99929091; called by muse, mutect2, varscan2
- MRPL23 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs576240953, COSV101203037; called by mutect2, varscan2
- MYMK | c.135+1G>A p.X45_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as rs757865413, COSV101301155; called by muse, mutect2, varscan2
- NEDD1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99901089; called by muse, mutect2, varscan2
- NKAPD1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as rs953935867, COSV99736259; called by muse, mutect2, varscan2
- NLRP8 | c.2510C>T p.S837F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.79); catalogued as COSV52590943; called by muse, mutect2, varscan2
- NRAP | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs1179231923, COSV63488313; called by muse, mutect2, varscan2
- OBSCN | c.14993C>T p.S4998F | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs915552522, COSV52827378; called by muse, mutect2, varscan2
- OR4K15 | c.978G>C p.K326N (on ENST00000305051; = p.K302N on NM_001005486.1) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100521058; called by muse, mutect2, varscan2
- OR8K5 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as COSV100537239, COSV57888096; called by muse, mutect2, varscan2
- OSBPL3 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100514231; called by muse, mutect2, varscan2
- OSBPL9 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100543565; called by muse, mutect2, varscan2
- PAK3 | c.1285C>T p.P429S (on ENST00000262836 / NM_001324328.2; = p.P414S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as COSV99457568; called by muse, mutect2, varscan2
- PAPLN | c.642C>G p.D214E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99389821; called by muse, mutect2, varscan2
- PCDHB15 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.513); catalogued as COSV99178987; called by muse, varscan2
- PCDHGC5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99340604; called by muse, mutect2, varscan2
- PCSK2 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1182474662, COSV99359834; called by muse, mutect2
- PDE3B | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.22); catalogued as COSV56381193, COSV99962700; called by muse, mutect2, varscan2
- PDIA2 | c.707T>G p.V236G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV99249935; called by mutect2, varscan2
- PFKFB1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | PolyPhen benign (0.12); catalogued as rs147029348, COSV66628750; called by muse, mutect2, varscan2
- PHTF1 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as COSV100760128, COSV63368774; called by muse, mutect2, varscan2
- PLXNA4 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV58146597; called by muse, mutect2, varscan2
- POTEF | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs368389320; called by muse, mutect2, varscan2
- PPP6R3 | c.2296G>A p.E766K (on ENST00000393800 / NM_001352375.2; = p.E686K on NM_018312.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.15); catalogued as COSV99676707; called by muse, mutect2, varscan2
- PTPRF | c.3250G>T p.A1084S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV100740986; called by muse, mutect2, varscan2
- PYHIN1 | c.815C>G p.S272* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100932363; called by muse, mutect2, varscan2
- RPGRIP1L | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as COSV100046436, COSV50913887; called by muse, mutect2
- RPS6KB2 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as rs777373346, COSV100396579; called by muse, mutect2
- RYR1 | c.12376G>A p.E4126K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100616019, COSV62103813, COSV62114183; called by muse, mutect2, varscan2
- SCNN1A | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99964789; called by muse, mutect2, varscan2
- SEMG1 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99725311; called by muse, mutect2, varscan2
- SGIP1 | c.320C>A p.S107* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV52766473, COSV52770350; called by muse, mutect2, varscan2
- SLC16A7 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as rs766869065, COSV53893376; called by muse, mutect2, varscan2
- SLC5A3 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV62971548; called by muse, mutect2, varscan2
- SLIT1 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99821611; called by muse, mutect2
- SMAD5 | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV101548130; called by muse, mutect2, varscan2
- SMG6 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs912691497, COSV99558336; called by muse, mutect2, varscan2
- SRCAP | c.6631G>C p.D2211H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99350395; called by muse, mutect2
- SRGN | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99653754; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | PolyPhen benign (0.001); catalogued as COSV99833397; called by muse, mutect2, varscan2
- ST8SIA2 | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | PolyPhen probably damaging (0.99); catalogued as COSV99184451; called by muse, mutect2, varscan2
- STAU1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs1426867997, COSV100574396, COSV61460630; called by muse, mutect2, varscan2
- SZT2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1557534581, COSV101285364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAS2R3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs140116022; called by muse, mutect2, varscan2
- TBXAS1 | c.1473G>C p.L491F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV99695501; called by muse, mutect2, varscan2
- TCEAL4 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs200167143, COSV101010267; called by muse, mutect2, varscan2
- TCIRG1 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99693435; called by muse, mutect2, varscan2
- TFB1M | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV100905211; called by muse, mutect2, varscan2
- THSD1 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1308504978, COSV99318919; called by muse, mutect2, varscan2
- TNC | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs770789816, COSV60791519; called by muse, mutect2, varscan2
- TP73 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100600990, COSV100601379; called by muse, mutect2, varscan2
- TRIOBP | c.3379C>T p.R1127C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs374785193; called by muse, mutect2, varscan2
- TSBP1 | c.997G>A p.V333I (on ENST00000617061; = p.V338I on NM_006781.5) | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.949); catalogued as COSV100898834; called by muse, mutect2, varscan2
- TTLL13P | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs545771428, COSV100296587; called by muse, mutect2, varscan2
- UBA6 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100451743, COSV59177029; called by muse, mutect2, varscan2
- USHBP1 | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99394605; called by muse, mutect2
- USP29 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99572209; called by muse, mutect2, varscan2
- VWCE | c.1469A>G p.Q490R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as COSV100075928; called by muse, mutect2, varscan2
- WDR33 | c.297G>C p.L99F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV100460235; called by muse, mutect2, varscan2
- XIRP2 | c.6642T>G p.S2214R (on ENST00000628543; = p.S2389R on NM_152381.6) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99742935, COSV99743957; called by muse, mutect2, varscan2
- ZFP36L1 | c.899C>A p.S300* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100322729; called by muse, mutect2, varscan2
- ZNF106 | c.3851C>G p.S1284* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99782728, COSV99782779; called by mutect2, varscan2
- ZNF227 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100480453; called by muse, mutect2, varscan2
- ZNF254 | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100741668, COSV61642484; called by muse, mutect2, varscan2
- ZNF512B | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs760018626, COSV99412159; called by muse, mutect2, varscan2
- ZNF569 | c.1035G>A p.M345I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100386514; called by muse, mutect2, varscan2
- ZNF611 | c.2037G>C p.K679N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100160346; called by muse, mutect2, varscan2
- ZNF638 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1172153973, COSV100039081; called by muse, mutect2, varscan2
- ZSCAN20 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100792645; called by muse, mutect2, varscan2
- INSRR | c.1150del p.I384Sfs*18 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- NTN1 | c.1286_1291del p.V429_T430del | In Frame Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- RHPN1 | c.140_154del p.E47_T52delinsA | In Frame Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- SLC6A9 | c.1967del p.P656Lfs*15 (on ENST00000360584 / NM_201649.4; = p.P602Lfs*15 on NM_006934.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- TRGV2 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- A2M | c.1611C>T p.V537= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs568909624, COSV59385687; called by muse, mutect2, varscan2
- ALPK3 | c.3627G>T p.G1209= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99361167; called by muse, mutect2, varscan2
- ANGEL1 | c.1560C>T p.I520= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as rs1470133203, COSV51875112; called by muse, mutect2, varscan2
- CACNA1E | c.5067C>T p.N1689= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs377382446; called by muse, mutect2, varscan2
- CCL5 | c.24C>T p.L8= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1407443936; called by muse, mutect2, varscan2
- CES1 | c.783C>T p.V261= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100828701; called by muse, mutect2, varscan2
- CRACD | c.2214G>A p.Q738= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV99949467; called by muse, mutect2, varscan2
- EIF2B2 | c.408G>A p.A136= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs772320060, COSV99837694; called by muse, mutect2, varscan2
- ERAL1 | c.208C>T p.L70= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV99650375, COSV99650463; called by muse, mutect2, varscan2
- FBXO30 | c.1257C>A p.G419= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99395245; called by muse, mutect2
- GABRB3 | c.192G>T p.G64= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100160341; called by muse, mutect2, varscan2
- GK5 | c.291G>A p.Q97= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV101242059; called by muse, mutect2, varscan2
- H4C3 | c.45T>C p.G15= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV100619574; called by muse, mutect2, varscan2
- HMG20A | c.177G>A p.Q59= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100287809; called by muse, mutect2, varscan2
- HNRNPCL1 | c.291G>A p.V97= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs981909786, COSV58610267; called by muse, mutect2, varscan2
- HRC | c.27C>T p.H9= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs765338813, COSV53255827; called by muse, varscan2
- IARS2 | c.579G>A p.E193= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV100228387; called by muse, mutect2, varscan2
- IL20 | c.396C>T p.C132= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100894159; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.94C>T p.L32= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as COSV99860857; called by muse, mutect2, varscan2
- KANSL2 | c.39G>A p.R13= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100770981, COSV63479633; called by muse, mutect2, varscan2
- MED16 | c.132C>T p.L44= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1054585973, COSV99515805; called by muse, mutect2, varscan2
- NCKAP1L | c.618C>G p.L206= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99515198; called by muse, mutect2, varscan2
- NTNG2 | c.10C>T p.L4= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100647523; called by muse, mutect2, varscan2
- OBSCN | c.8919C>T p.T2973= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99480043; called by muse, mutect2
- PASD1 | c.1542G>A p.K514= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100949417; called by muse, mutect2, varscan2
- PCDHGA6 | c.2034C>T p.L678= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV53978990; called by muse, mutect2, varscan2
- PIGA | c.456G>A p.T152= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs776453997, COSV61237827; called by muse, mutect2, varscan2
- PIGU | c.864C>T p.F288= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV54160310, COSV99466569; called by muse, mutect2, varscan2
- PREB | c.1185C>G p.L395= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99574567; called by muse, varscan2
- PRR19 | c.243G>A p.V81= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1358069176, COSV100003918; called by muse, mutect2, varscan2
- PTK2B | c.1596G>A p.Q532= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100593292, COSV100594033, COSV57762381; called by muse, mutect2, varscan2
- RIN1 | c.1830C>T p.L610= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100254739; called by muse, mutect2, varscan2
- RYR3 | c.9327G>T p.L3109= (on ENST00000389232; = p.L3110= on NM_001036.6) | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV101212991; called by muse, mutect2, varscan2
- SCFD2 | c.1653G>A p.R551= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV101189387; called by muse, mutect2
- SIN3B | c.3057C>G p.L1019= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1465248896, COSV99931801; called by muse, mutect2, varscan2
- SLC12A3 | c.759C>T p.I253= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs150890628; called by muse, mutect2, varscan2
- TICRR | c.399G>A p.L133= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99176658; called by muse, mutect2, varscan2
- TMEM254 | c.69C>T p.L23= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV100953566; called by muse, mutect2, varscan2
- TOP2B | c.1521C>T p.L507= (on ENST00000264331 / NM_001330700.2; = p.L502= on NM_001068.3) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1037702066, COSV99979838; called by muse, mutect2, varscan2
- TP53I3 | c.672G>A p.K224= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99272849; called by muse, mutect2, varscan2
- UBA1 | c.1830G>A p.V610= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100255781; called by muse, mutect2, varscan2
- VAT1L | c.15C>T p.G5= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs377554393, COSV100213626; called by muse, mutect2, varscan2
- VIT | c.771C>T p.F257= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV101007461, COSV64897465; called by muse, mutect2, varscan2
- WDR11 | c.57C>A p.L19= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99676658; called by muse, mutect2
- ZC3H12D | c.27C>T p.F9= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV101116790, COSV66324220; called by muse, mutect2, varscan2
- ZC3H15 | c.1164G>A p.E388= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100552120; called by muse, mutect2, varscan2
- ZNF512B | c.1440C>T p.V480= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs767276357, COSV99412157; called by muse, mutect2, varscan2
- ZNF536 | c.1029C>T p.N343= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs760335471, COSV62827992; called by muse, mutect2, varscan2
- ZNF581 | c.516G>A p.P172= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV54402320; called by muse, mutect2, varscan2
- ZNF700 | c.1197C>T p.F399= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV99583586; called by muse, mutect2, varscan2
- ZNF746 | c.1524C>T p.S508= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs779254209, COSV100502502; called by muse, varscan2
- ASIC2 | c.556-179509G>A | Intron (SNP) | VAF 10/42 reads (24%) | catalogued as rs748966440, COSV99860344; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14742G>C | Intron (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100231758, COSV100232706; called by muse, mutect2, varscan2
- MFRP | chr11:119346096 G>C | 5'Flank (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100793479; called by muse, mutect2, varscan2
- MIR573 | n.12C>T | RNA (SNP) | VAF 31/116 reads (27%) | catalogued as rs1431684992; called by muse, mutect2, varscan2
- ODF2 | c.124-292C>T | Intron (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100654685; called by muse, mutect2
- PDE4DIP | c.637-7075G>A | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100519807; called by muse, mutect2, varscan2
- PDE4DIP | c.637-6954G>A | Intron (SNP) | VAF 6/21 reads (29%) | catalogued as rs782801480, COSV57690647, COSV57700111, COSV57736804; called by muse, mutect2, varscan2
